Surgical pathology report (de-identified scan), TCGA case TCGA-6D-AA2E, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-6D-AA2E-01A (Primary Tumor).

[page 1 of 3]
SPEC #: Obtained: Subm Dr:

STATUS: Received:

CLINICAL HISTORY:
RIGHT RENAL MASS

ICD-O-3
Carcinoma, renal cell, clear cell
Site R Kidney NOS
8310/3
664.9
J12/14/14

SPECIMEN/PROCEDURE :
1. RIGHT KIDNEY - NEPHRECTOMY

IMPRESSION:

KIDNEY, RIGHT, RADICAL NEPHRECTOMY:

- . Clear cell renal cell carcinoma, Fuhrman grade 2.
- . Size of tumor: 6.5 x 5.0 x 3.9 cm.
- . Location: middle of kidney.
- . Extent: limited to kidney, no involvement of renal pelvis.
- . Resection margins:
- . Vascular margin free of tumor.
- . Peripheral resection margin free of tumor.
- . Tumor is 1 from the nearest (perirenal adipose tissue) margin.
- . Please refer to check list for details.
- . Pathologic TNM (AJCC 7th edition): pT1b.
- . Glomerulosclerosis is present in a minor component of glomeruli.
- . Focal fibrosis and focal chronic inflammatory cell infiltration.

KIDNEY: NEPHRECTOMY, PARTIAL OR RADICAL CASE SUMMARY

PROCEDURE

Radical nephrectomy

SPECIMEN LATERALITY

Right

TUMOR SITE

Middle

TUMOR SIZE (largest tumor if multiple)

Greatest dimension: 6.5 cm

Additional dimensions: 5.0 x 3.9 cm

TUMOR FOCALITY

Unifocal

MACROSCOPIC EXTENT OF TUMOR

Tumor limited to kidney

HISTOLOGIC TYPE

Clear cell renal cell carcinoma

[page 2 of 3]
IMPRESSION: (continued)

SARCOMATOID FEATURES

Not identified

TUMOR NECROSIS (any amount)

Not identified

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE)

G2: Nuclei slightly irregular, approximately 15 m; nucleoli evident

MICROSCOPIC TUMOR EXTENSION

Tumor limited to kidney

MARGINS

Margins uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION

(excluding renal vein and its muscle containing segmental branches and inferior vena cava)

Not identified

PATHOLOGIC STAGING (pTNM)

PRIMARY TUMOR (pT)

pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES (pN)

No nodes submitted or found

DISTANT METASTASIS (pM)

Not applicable

PATHOLOGIC FINDINGS IN NONNEOPLASTIC KIDNEY

Significant pathologic alterations

Glomerular disease (specify type): glomerulosclerosis

Tubulointerstitial disease (specify type): chronic inflammatory cell infiltration, focal, focal fibrosis.

OTHER TUMORS AND/OR TUMOR-LIKE LESIONS

None

Pathologic TNM (AJCC 7th edition): pT1b

Dictated by:

Entered:

COMMENT:

Case reviewed at the

Entered:

[page 3 of 3]
GROSS DESCRIPTION:

Received in formalin in a container labeled with patient's name, hospital number and "right renal mass" is a 450 gram right nephrectomy specimen including the kidney (12 x 9.0 x 5.0 cm) and surrounding perirenal fat, measuring in thickness 0.5-0.8 cm. A ureter extends from the renal pelvis (5 cm in length x 0.5 cm in diameter). The entire specimen is inked black. Cut sections show a cortically based well-circumscribed encapsulated mass located at the midpole, 6.5 x 5.0 x 3.9 cm. Upon opening, the mass is heterogeneous, consisting of a tan, yellow-brown tumor and two small cystic areas containing clear mucinous content. The tumor extends near (within <0.1 cm) to the capsule surface margin. There is a tan-white nodule measuring 0.5 x 0.3 present in the upper portion of the kidney. No renal vein or the perirenal fat involvement is identified grossly. The remainder of the renal cortex is tan-brown with a well-defined corticomedullary junction. The pelvis and calyces are covered with smooth, glistening, tan-pink mucosa. The adipose tissue is thinly sectioned and no lymph nodes are found. Sections are submitted as follows:

- Cassette 1A-1D: Tumor, full cross-section in relation to renal capsule and adjacent normal.
- Cassette 1E-1G: Tumor, representative sections
- Cassette 1H-1J: Tumor in relation to ureter
- Cassette 1K: Separated nodule, representative sections
- Cassette 1L: Tumor in relation to the nearest vessels
- Cassette 1M: Tumor in relation to pelvis
- Cassette 1N: Uninvolved kidney with renal pelvis
- Cassette 1P: Ureteral margin
- Cassette 1Q: Renal vein margin

Dictated by:
Entered:

COPIES TO:

Undefined Provider

CPT Codes:
KIDNEY, PART RESECTION TUMOR/88307

ICD9 Codes:
189.0
Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 93dc1870-386d-46a6-8146-fff3ab872483 (TCGA-6D-AA2E.2F9C29AE-B1C6-4A2B-9CC8-E5113138F864.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).